TARGET case TARGET-30-PAPKWN — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Other and ill-defined sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ab3d4eec-32cf-56be-a7f0-fcd4ecf6c423

Demographics
Sex at birth: female; Race: white; Age at index: 1 years; Vital status: Dead; Days to death: 465 days (1.3 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C76.0; Tissue or organ of origin: Head, face or neck, NOS; Classification of tumor: primary; Age at diagnosis: 1.9 years (710 days); Year of diagnosis: 2006; Days to last follow up: 465 days (1.3 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: High.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (2 entries)
- Days to follow up: 260 days; Progression or recurrence anatomic site: Bone marrow; Days to first event: 260 days; First event: Relapse.
- Days to follow up: 465 days (1.3 years); Year of follow up: 2007.

Molecular and laboratory tests
- MYCN amplification: Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (3 samples)
- Samples TARGET-30-PAPKWN-01A, TARGET-30-PAPKWN-01B (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAPKWN-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 465
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.6
- Histology: Unfavorable
- ICDO Description: Head, face or neck, NOS Cheek, NOS Jaw, NOS Nose, NOS Cervical region, NOS Supraclavicular region, NOS
